Gene-level copy-number profile of tumor specimen TARGET-10-PATPDA-09A from TARGET case TARGET-10-PATPDA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (747 days).
Specimen TARGET-10-PATPDA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.24169c82-c0e2-5518-8e41-b8947850e376.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATPDA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 390 have no estimate.
https://portal.gdc.cancer.gov/files/1e97df70-d219-44ff-aba3-cbc7b5d4c2f7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 93; copy number 1: 2,448; copy number 2: 56,860; copy number 3: 751; copy number 4: 18; copy number 5: 63.

Homozygous deletions (total copy number 0; autosomes only): 93 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:108,047,545–108,168,956, 1 gene (within-gene range 0–2): LEF1.
- chr7:38,239,580–38,378,804, 23 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2.
- chr9:21,802,636–22,029,594, 6 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3.
- chr14:22,011,910–22,499,749, 63 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 63 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,895,772, 63 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 61. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
